Somatic mutation profile of tumor specimen TCGA-AB-2917-03A (aliquot TCGA-AB-2917-03A-01W-0732-08) from TCGA case TCGA-AB-2917, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 41.4 years (15,128 days).
Specimen TCGA-AB-2917-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1f1b065-d3cb-4197-be52-4a4e7b5556ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2917-11A (Solid Tissue Normal), aliquot TCGA-AB-2917-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6368f4b-6aab-4a6a-ac85-386ce7c327d7

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Nonsense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1762C>T p.Q588* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as rs1486082302, COSV60103144; ClinVar: pathogenic; called by muse, varscan2
- KRAS | c.108A>G p.I36M | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs727503109, CM070965, COSV55721142; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50056804; called by muse, mutect2, varscan2
- CCDC180 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as rs151161375; called by muse, mutect2, varscan2
- DIAPH2 | c.3223C>T p.R1075W | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757274818, COSV61273929; called by muse, mutect2, varscan2
- GPR15 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as rs746880733, COSV52520058; called by muse, varscan2
- NCR2 | c.161G>A p.W54* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as rs772201667, COSV100897235; called by muse, mutect2, varscan2
- SLC7A13 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as rs144944362; called by muse, mutect2, varscan2
- UNC5D | c.955G>A p.V319I | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.381); catalogued as rs545883862, COSV54802501; called by mutect2, varscan2
- GPR78 | c.900G>A p.P300= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs374353570; called by muse, varscan2
